Somatic mutation profile of tumor specimen 0DNMAP from CCDI case PBCAXK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,111 days).
Specimen 0DNMAP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53b2f468-fa1d-44b6-a975-024336ee05db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNM9W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67d9bba2-16d6-40c8-8a2f-63ee10288b95

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGF1R | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 36/687 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV51271054, COSV51279483, COSV51287490; called by muse, mutect2
- OR8I2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 76/1338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56169264; called by muse, mutect2
- PM20D2 | c.431T>C p.L144S | Missense Mutation (SNP) | VAF 29/473 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1016733043; called by muse, mutect2
- VPS41 | c.2452T>C p.F818L | Missense Mutation (SNP) | VAF 130/951 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV59648552; called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 48/942 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- LMBRD2 | c.732G>A p.L244= | Silent (SNP) | VAF 27/645 reads (4%) | called by muse, mutect2
